FM case AD3033 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Adenomas and Adenocarcinomas; Primary site: Skin.
https://portal.gdc.cancer.gov/cases/29b6554b-c140-4115-81b1-3a849ff395e8

Male, 82.4 years: Merkel cell carcinoma (ICD-O-3 8247/3) of the skin; primary biopsied or resected from the skin. Tumor nuclei on the sequenced sample's slide: 40% (pathologist estimate recorded by GDC). Sample type: Primary Tumor.
